Somatic mutation profile of tumor specimen TARGET-10-PARETC-09A (aliquot TARGET-10-PARETC-09A-01D) from TARGET case TARGET-10-PARETC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,052 days).
Specimen TARGET-10-PARETC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2699c18-98be-4e73-b8f8-b11287c4af8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARETC-10A (Blood Derived Normal), aliquot TARGET-10-PARETC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91ce4b6a-eae6-45ce-b8b9-1b012084bcde

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 3, Nonsense Mutation 2, RNA 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs759103275, COSV54387946, COSV99710963; called by muse, mutect2, varscan2
- AGTPBP1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV100429848; called by muse, mutect2, varscan2
- ANO3 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs768115640; called by muse, mutect2, varscan2
- CBL | c.1199T>A p.M400K | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50632333; called by muse, mutect2, varscan2
- CPA4 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV55979037; called by muse, mutect2, varscan2
- FSCB | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61217430; called by muse, mutect2, varscan2
- MYO16 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV51800237; called by muse, mutect2, varscan2
- RAB41 | c.560G>A p.R187H (on ENST00000374473 / NM_001363807.1; = p.R186H on NM_001032726.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs760694654; called by muse, mutect2, varscan2
- ZFYVE28 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746694468; called by muse, mutect2, varscan2
- MGA | c.2944G>T p.G982* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- PCDHA7 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PYDC1 | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ROBO4 | c.2297C>T p.S766F | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SFSWAP | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ST7 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VIP | c.336-6C>A | Splice Region (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- CCNP | c.462C>T p.G154= | Silent (SNP) | VAF 69/187 reads (37%) | called by muse, mutect2, varscan2
- METTL17 | c.759A>G p.V253= | Silent (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- OR10AG1 | c.655T>C p.L219= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- SNX25 | c.1905G>A p.G635= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV53013073; called by muse, mutect2, varscan2
- TDRD12 | c.3267C>T p.R1089= (on ENST00000444215; = p.R1094= on NM_001366102.1) | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1425262945, COSV71445625; called by muse, mutect2, varscan2
- TTN | c.48477C>T p.I16159= (on ENST00000591111; = p.I8735= on NM_003319.4) | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs1198906739, COSV100626201; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503275 A>G | 5'Flank (SNP) | VAF 35/81 reads (43%) | catalogued as rs924914544; called by muse, mutect2, varscan2
- AP002414.4 | n.556G>A | RNA (SNP) | VAF 7/12 reads (58%) | catalogued as rs1421089225; called by muse, mutect2
- CEP126 | c.507-1399C>T | Intron (SNP) | VAF 141/361 reads (39%) | called by muse, mutect2, varscan2
- LINC01517 | n.461G>A | RNA (SNP) | VAF 26/81 reads (32%) | catalogued as rs1382972680; called by muse, mutect2, varscan2
- NXF3 | c.29-4031C>T | Intron (SNP) | VAF 16/79 reads (20%) | catalogued as rs917976034; called by muse, mutect2, varscan2
- TAMM41 | c.*63G>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- ZNF181 | c.9+1158del | Intron (DEL) | VAF 54/211 reads (26%) | called by pindel, varscan2
